Gene-level copy-number profile of tumor specimen MP2PRT-PARERN-TMP1-A from MP2PRT case MP2PRT-PARERN, project MP2PRT-ALL (Molecular Profiling to Predict Response to Treatment for Acute Lymphoblastic Leukemia). Sex at birth: female; Vital status: Alive; Primary diagnosis: Acute lymphoblastic leukemia, NOS; Tissue or organ of origin: Bone marrow; Age at diagnosis: 6.3 years (2,318 days).
Specimen MP2PRT-PARERN-TMP1-A: Sample type: Blood Derived Cancer - Bone Marrow; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Whole Bone Marrow; Biospecimen anatomic site: Bone Marrow; Preservation method: Cryopreserved.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file 102e4e77-f0be-4e26-bdc8-0073fe4506cc.wgs.ASCAT.gene_level.copy_number_variation.tsv, workflow AscatNGS on whole-genome sequencing of the tumor/normal pair, germline comparator MP2PRT-PARERN-NM1-A (blood derived cancer - bone marrow, post-treatment); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 2,241 have no estimate.
https://portal.gdc.cancer.gov/files/20066bf9-856c-4b1a-a14c-a7828880dea2

Most common (modal) total copy number across autosomal genes: 2 — the diploid value.
Genes by total copy number (all chromosomes): copy number 0: 207; copy number 1: 764; copy number 2: 53,137; copy number 3: 3,552; copy number 4: 700; copy number 5: 22.

Homozygous deletions (total copy number 0; autosomes only): 207 genes in 7 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr2:88,811,186–89,245,596, 40 genes (within-gene range 0–3): MALLP2, AC244205.1, MIR4436A, IGKC, IGKJ5, IGKJ4, IGKJ3, IGKJ2, IGKJ1, IGKV4-1, IGKV5-2, IGKV7-3, PGBD4P5, IGKV2-4, IGKV1-5, IGKV1-6, IGKV3-7, IGKV1-8, IGKV1-9, IGKV2-10, IGKV3-11, IGKV1-12, IGKV1-13, IGKV2-14, IGKV3-15, IGKV1-16, IGKV1-17, IGKV2-18, IGKV2-19, IGKV3-20, IGKV6-21, IGKV1-22, IGKV2-23, IGKV2-24, IGKV3-25, IGKV2-26, AC244255.1, IGKV1-27, IGKV2-29, IGKV2-30.
- chr2:90,121,786–90,173,414, 3 genes (within-gene range 0–2): IGKV2D-14, IGKV1D-12, IGKV3D-11.
- chr14:22,438,547–22,459,156, 7 genes (within-gene range 0–3): TRDD1, TRDD2, TRDD3, TRDJ1, TRDJ4, TRDJ2, TRDJ3.
- chr14:22,483,004–22,531,138, 40 genes (within-gene range 0–3): TRAJ53, TRAJ52, TRAJ51, TRAJ50, TRAJ49, TRAJ48, TRAJ47, TRAJ46, TRAJ45, TRAJ44, TRAJ43, TRAJ42, TRAJ41, TRAJ40, TRAJ39, TRAJ38, TRAJ37, TRAJ36, TRAJ35, TRAJ34, TRAJ33, TRAJ32, TRAJ31, TRAJ30, TRAJ29, TRAJ28, TRAJ27, TRAJ26, TRAJ25, TRAJ24, TRAJ23, TRAJ22, TRAJ21, TRAJ20, TRAJ19, TRAJ18, TRAJ17, TRAJ16, TRAJ14, TRAJ13.
- chr14:105,672,308–106,481,706, 114 genes (within-gene range 0–2) (broad region; genes not listed).
- chr14:106,531,141–106,538,344, 2 genes (within-gene range 0–1): IGHVIII-47-1, IGHV3-48.
- chr14:106,618,894–106,619,173, 1 gene (within-gene range 0–1): IGHV3-57.

Amplified relative to the modal value (total copy number ≥ 5, i.e. more than twice the modal value of 2; autosomes only): 22 genes in 1 contiguous region (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr21:46,136,262–46,691,226, 22 genes, copy number 5: FTCD, FTCD-AS1, SPATC1L, AP001468.1, LSS, AP001469.1, MCM3AP-AS1, MCM3AP, AP001469.2, AP001469.3, YBEY, C21orf58, PCNT, AP000471.1, RPL18AP2, DIP2A, DIP2A-IT1, RNU6-396P, S100B, PRMT2, DSTNP1, RPL23AP4.

Autosomal genes at a single copy (total copy number 1): 764. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
